Gene-level copy-number profile of tumor specimen ALCH-B2NP-TTP1-A from ALCHEMIST case ALCH-B2NP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.8 years (26,969 days).
Specimen ALCH-B2NP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e619f6bd-0b48-462e-a873-5e7ea78d8e68.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2NP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/5e20f84b-0b85-4962-b154-966077fa81c7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,824; copy number 2: 55,001; copy number 3: 1,445; copy number 4: 52; copy number 5: 56; copy number 9: 1; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:93,955,597–93,959,140, 1 gene: BARX1-DT.
- chr16:89,919,165–89,968,060, 4 genes (within-gene range 0–1): AC092143.1, AC092143.2, TUBB3, DEF8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,549,920–2,565,382, 2 genes, copy number 5: TNFRSF14-AS1, TNFRSF14.
- chr1:2,581,560–2,591,469, 2 genes, copy number 5 (within-gene range 2–5): AL139246.3, PRXL2B.
- chr15:89,830,599–90,502,239, 39 genes, copy number 5: AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr15:96,756,987–97,560,702, 12 genes, copy number 5: FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3.
- chr16:89,906,157–89,918,233, 1 gene, copy number 9 (within-gene range 1–9): AC092143.3.
- chr19:40,121,311–40,122,168, 1 gene, copy number 5: VN1R96P.
- chr21:43,461,960–43,479,534, 1 gene, copy number 13 (within-gene range 3–13): LINC00313.

Autosomal genes at a single copy (total copy number 1): 1,813. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
